Somatic mutation profile of tumor specimen TCGA-55-A57B-01A (aliquot TCGA-55-A57B-01A-12D-A397-08) from TCGA case TCGA-55-A57B, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.6 years (29,452 days).
Specimen TCGA-55-A57B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ddbdc9e-468e-4d98-bddd-3dd0d4c73be3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A57B-10A (Blood Derived Normal), aliquot TCGA-55-A57B-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a042668f-e877-4eee-9540-f14ded1fed45

The open-access MAF lists 41 somatic variants for this specimen: 36 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 4, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 16/98 reads (16%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- BRINP2 | c.686C>G p.T229S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV100838493; called by muse, mutect2
- BSN | c.4150A>G p.T1384A | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99609956; called by muse, mutect2, varscan2
- BTBD9 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs1442572403, COSV58428139; called by muse, mutect2, varscan2
- CASZ1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as rs969267868, COSV100682234; called by muse, mutect2, varscan2
- CHTF8 | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV99544790; called by muse, varscan2
- DEPDC5 | c.2387G>A p.R796Q (on ENST00000400246; = p.R865Q on NM_014662.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99836716; called by muse, mutect2
- ERMN | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs761673159, COSV101263073; called by muse, mutect2, varscan2
- FCRL5 | c.1980C>G p.I660M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100708810, COSV100709378, COSV62515073; called by muse, mutect2, varscan2
- GRM6 | c.1686G>A p.M562I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as COSV51447039; called by muse, mutect2, varscan2
- HPS4 | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as COSV100404761; called by mutect2, varscan2
- KCNA5 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99364238; called by muse, mutect2, varscan2
- MAFA | c.878T>A p.V293E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100339235; called by muse, mutect2, varscan2
- NLRP4 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as rs766831042, COSV100017269; called by muse, mutect2, varscan2
- NME9 | c.175G>T p.D59Y (on ENST00000333911 / NM_001349024.2; = p.D37Y on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100444914; called by muse, mutect2, varscan2
- NPSR1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1256090452, COSV100707238; called by muse, mutect2, varscan2
- OR2T1 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100822333, COSV63542946; called by muse, mutect2, varscan2
- PDK1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.361); catalogued as COSV99961299; called by mutect2, varscan2
- PHF21B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs751148938, COSV100504114; called by muse, mutect2
- PPRC1 | c.2625G>T p.M875I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99532177; called by muse, mutect2, varscan2
- SEMA3A | c.1483T>C p.S495P | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99548134; called by muse, mutect2, varscan2
- TAGAP | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs371800256; called by muse, mutect2, varscan2
- TDRD5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV99677292; called by muse, mutect2, varscan2
- TMEM54 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100232007; called by muse, mutect2
- TRIM10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs760940395, COSV64989959; called by muse, mutect2, varscan2
- ZCCHC8 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777624068, COSV100288516; called by muse, mutect2, varscan2
- ZKSCAN1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1167524040, COSV100164374; called by muse, mutect2, varscan2
- ZNF354A | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100234669; called by muse, mutect2
- ZNF671 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV58054164; called by muse, mutect2, varscan2
- ZNRF3 | c.1599C>G p.H533Q (on ENST00000544604 / NM_001206998.2; = p.H433Q on NM_032173.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100239062; called by muse, mutect2, varscan2
- HNF1B | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- KLHL10 | c.1514del p.N505Tfs*56 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- MAP4K3 | c.2272_2288del p.N758Ffs*44 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- Z83844.2 | c.551_568del p.A184_R189del | In Frame Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- CRTAC1 | c.330G>T p.R110= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100086199; called by muse, mutect2
- IRGC | c.291G>A p.S97= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs11555892; called by muse, mutect2, varscan2
- PGPEP1L | c.228C>T p.A76= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs544546387, COSV66709464; called by muse, mutect2
- PLEKHG4 | c.1098G>A p.E366= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100846532; called by muse, mutect2, varscan2
- ZDHHC23 | c.-1C>T | 5'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs964258355, COSV57629054, COSV57630290; called by muse, mutect2
